Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7817, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7817-01B (Primary Tumor).

[page 1 of 2]
ADDENDUM REPORT

This addendum report is being issued to add additional information from the container labels. The container actually had two patient labels, one stating prostate and the other stating pelvic lymph nodes.

On additional inspection of the specimen, no lymph nodes were identified.

Addendum Report Issued By:

DIAGNOSIS

DIAGNOSIS:

Prostate and pelvic lymph nodes, radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 3.8 x 3.5 x 1.0 cm.
3. Gleason grade:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 7/10.
4. Tumor involves both lobes.
5. Tumor quantitation: Tumor involves approximately 5% of tissue sampled.
6. Seminal vesicle involvement: Yes (right).
7. Extraprostatic tumor extension: Yes, in section adjacent to right seminal vesicle.
8. Lymphovascular space invasion: Not identified.
9. Perineural invasion: Yes, extensive.
10. High grade PIN: Present.

Surgical Margin Status:

1. Bladder neck- negative.
2. Apical/inferior- Positive.
3. Inked prostatic margin: Positive, at right prostate adjacent to right seminal vesicle.

Lymph Node Status:

1. No lymph nodes are present with the specimen.

Other:

1. Benign prostatic hyperplasia, High Grade PIN, and chronic prostatitis.
2. Focal organizing thrombus in periprostatic blood vessel.
3. TNM stage: T3b NX MX.

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: prostate, NOS C61.9

1/16/15

fw

COMMENTS:

There is extensive tumor in the section adjacent to right seminal vesicle, although there is a distance of approximately 1.0 mm from the seminal vesicle epithelium to the tumor. Extraprostatic extension is also present in the section (block #1).

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Prostate and pelvic lymph nodes

SPECIMEN DATA

[page 2 of 2]
[REDACTED]

The specimen is received in a single formalin-filled container with two labels each with the patient's name [REDACTED]. The first label contains 'prostate' and the second label additionally states 'pelvic lymph nodes'. The specimen consists of a 45.5 gram, 5.0 x 4.5 x 4.0 cm prostate gland, received with attached bilateral adnexa, which has overall dimensions of 3.8 x 3.5 x 1.0 cm. The capsule is pink-tan and shaggy. The specimen is inked as follows: right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the specimen is serially sectioned from apex to base to reveal a pink-tan focally cystic and glistening cut surface with diffuse peritumoral nodularity. A discrete mass is not identified. No additional tissue or lymph nodes are present within the container. Representative sections are submitted in cassettes 1 through 18 labeled as follows: 1, right prostate/seminal vesicle junction; 2, left prostate/seminal vesicle junction; 3 and 4, apical margin, perpendicular; 5 and 6, base margin, perpendicular; 7 through 9, right anterior, apex to base; 10 through 12, right posterior, apex to base; 13 through 15, left anterior, apex to base; 16 through 18, left posterior, apex to base. Additionally, a yellow and green cassette are submitted for genomics research, each labeled [REDACTED].

Source: NCI Genomic Data Commons file 08a174cf-0bd3-4f20-9f1e-495ed44bef95 (TCGA-HC-7817.A1E3EC71-D7D2-4286-A12F-78ADFD27E53C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).